Somatic mutation profile of tumor specimen TCGA-DU-A7TG-01A (aliquot TCGA-DU-A7TG-01A-21D-A34J-08) from TCGA case TCGA-DU-A7TG, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 40.2 years (14,671 days).
Specimen TCGA-DU-A7TG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4d0764ff-da71-443d-8d0b-36dd26d0e114.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-A7TG-10A (Blood Derived Normal), aliquot TCGA-DU-A7TG-10A-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e75c93a1-7469-456d-8cd9-473f2cc26093

The open-access MAF lists 12 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 8, Silent 3, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 10/117 reads (9%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- ADGRF4 | c.1315C>T p.R439C | Missense Mutation (SNP) | VAF 36/170 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs536284658, COSV51956797; called by muse, mutect2, varscan2
- COL6A1 | c.1435G>A p.G479S | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1430198828, COSV100720464; called by muse, mutect2, varscan2
- DNHD1 | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as rs371771404, COSV99600954; called by muse, mutect2, varscan2
- ELK4 | c.1247A>G p.D416G | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99222522; called by muse, mutect2, varscan2
- TAF1L | c.2893T>C p.C965R | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99645401; called by muse, mutect2, varscan2
- WDR27 | c.442A>T p.M148L | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.03); catalogued as COSV100359789; called by muse, mutect2, varscan2
- ZNF280D | c.2510A>G p.E837G | Missense Mutation (SNP) | VAF 43/222 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV99975121; called by muse, mutect2, varscan2
- BMP5 | c.745del p.V249Sfs*6 | Frame Shift Del (DEL) | VAF 18/141 reads (13%) | called by mutect2, pindel, varscan2
- CDH17 | c.1095T>C p.H365= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as COSV50338842, COSV99218005; called by muse, mutect2, varscan2
- KMT2C | c.9711T>C p.V3237= | Silent (SNP) | VAF 22/140 reads (16%) | catalogued as COSV100076376; called by muse, mutect2, varscan2
- TEKT1 | c.945G>A p.T315= | Silent (SNP) | VAF 17/211 reads (8%) | catalogued as rs536852793, COSV100106020; called by muse, mutect2
